Somatic mutation profile of tumor specimen 0DPBG4 from CCDI case PBCDHN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 12.2 years (4,458 days).
Specimen 0DPBG4: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86528bc1-c19c-4360-886f-5f27ed0bd350.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPBFD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33c3ce1e-613d-4ae6-b831-a53407e862cd

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, Splice Site 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 348/536 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, varscan2
- CBR4 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 120/347 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs115240450; called by muse, varscan2
- CNRIP1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 138/550 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.157); catalogued as rs757038505, COSV55148600, COSV55150547; called by muse, varscan2
- FAM71B | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 149/402 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs767513722, COSV57227377; called by muse, varscan2
- FCGBP | c.12058G>A p.V4020I | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as rs1463762229; called by muse, varscan2
- KHDC1L | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 150/325 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1182759945, COSV64893344; called by muse, varscan2
- PCLO | c.8666C>T p.S2889F | Missense Mutation (SNP) | VAF 135/631 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV61644724; called by muse, varscan2
- TJP2 | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs148629740; called by muse, varscan2
- ADAMTS18 | c.2801+2T>A p.X934_splice | Splice Site (SNP) | VAF 165/364 reads (45%) | called by muse, varscan2
- DNAH14 | c.1360A>G p.N454D (on ENST00000445597; = p.N435D on NM_001145154.3) | Missense Mutation (SNP) | VAF 202/477 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, varscan2
- OR2V2 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 136/344 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, varscan2
- TRIM51GP | c.111del p.C38Vfs*33 | Frame Shift Del (DEL) | VAF 288/1361 reads (21%) | called by pindel, varscan2
- ZEB2 | c.-69-4_-69delinsTGTT | Splice Site (DEL) | VAF 33/72 reads (46%) | called by pindel, varscan2*
- CTSO | c.192C>T p.T64= | Silent (SNP) | VAF 156/426 reads (37%) | catalogued as rs758618667, COSV101467860; called by muse, varscan2
- OR13C9 | c.933G>T p.P311= | Silent (SNP) | VAF 150/396 reads (38%) | catalogued as COSV52240578; called by muse, varscan2
- OXSM | c.1158G>T p.L386= | Silent (SNP) | VAF 220/512 reads (43%) | called by muse, varscan2
- PSG11 | c.639A>G p.G213= | Silent (SNP) | VAF 132/490 reads (27%) | called by muse, varscan2
- RASAL2 | c.243G>A p.L81= | Silent (SNP) | VAF 102/274 reads (37%) | catalogued as rs1247325929; called by muse, varscan2
- RBMS2 | c.1074G>T p.T358= | Silent (SNP) | VAF 82/292 reads (28%) | called by muse, varscan2
- TNIP3 | c.975G>A p.P325= | Silent (SNP) | VAF 111/300 reads (37%) | catalogued as rs202104406; called by muse, varscan2
- FXYD5 | c.*67G>C | 3'UTR (SNP) | VAF 37/110 reads (34%) | catalogued as COSV61569550; called by muse, varscan2
